Somatic mutation profile of tumor specimen BA2255D (aliquot aq-BA2255D) from BEATAML1.0 case 2539, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with t(9;11)(p22;q23), MLLT3-MLL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.0 years (22,999 days).
Specimen BA2255D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f8669f3b-96de-401d-a4c5-a5e4bd5d7acf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2997D (Solid Tissue Normal), aliquot aq-BA2997D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e8aa7aca-ac72-4b13-b898-7439c8485034

The open-access MAF lists 17 somatic variants for this specimen: 13 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 3, Nonsense Mutation 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2503G>C p.D835H | Missense Mutation (SNP) | VAF 13/174 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913488, COSV54042116, COSV54042636, COSV54045151; ClinVar: pathogenic; called by muse, mutect2
- PTPN11 | c.1508G>T p.G503V | Missense Mutation (SNP) | VAF 32/298 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs397507546, CM086897, CM115675, CM1314033, COSV61004973, COSV61005158, COSV61008174; ClinVar: other / likely pathogenic; called by muse, mutect2, varscan2
- CCDC141 | c.1955C>T p.T652I | Missense Mutation (SNP) | VAF 49/115 reads (43%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as COSV99836750; called by muse, mutect2, varscan2
- KLHL32 | c.1120C>G p.R374G | Missense Mutation (SNP) | VAF 49/108 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100987179, COSV65113323; called by muse, mutect2, varscan2
- PXDNL | c.4100C>T p.T1367M | Missense Mutation (SNP) | VAF 141/214 reads (66%) | SIFT tolerated (0.09); PolyPhen benign (0.298); catalogued as rs201574671; called by muse, mutect2, varscan2
- RPTOR | c.1963G>A p.G655R | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV60808991; called by muse, mutect2, varscan2
- TMC3 | c.672C>A p.Y224* | Nonsense Mutation (SNP) | VAF 29/52 reads (56%) | catalogued as COSV63923641; called by muse, mutect2, varscan2
- UNC13C | c.6280C>T p.L2094F | Missense Mutation (SNP) | VAF 91/231 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV52876513; called by muse, mutect2, varscan2
- USH2A | c.1438G>A p.V480I | Missense Mutation (SNP) | VAF 138/295 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.711); catalogued as rs138694314; ClinVar: uncertain significance; called by muse, mutect2
- ZNF595 | c.382G>T p.G128* | Nonsense Mutation (SNP) | VAF 22/294 reads (7%) | catalogued as rs1442639704; called by muse, mutect2
- NYAP2 | c.1633C>G p.L545V | Missense Mutation (SNP) | VAF 49/119 reads (41%) | SIFT tolerated (0.53); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- PLRG1 | c.97G>C p.V33L | Missense Mutation (SNP) | VAF 70/163 reads (43%) | SIFT tolerated (0.89); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLCO4C1 | c.1397C>A p.T466K | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ADCY9 | c.882C>T p.I294= | Silent (SNP) | VAF 63/119 reads (53%) | catalogued as COSV53574644; called by muse, mutect2, varscan2
- NBN | c.15G>A p.L5= | Silent (SNP) | VAF 64/202 reads (32%) | catalogued as rs1363180098; called by muse, mutect2, varscan2
- PEG3 | c.93G>A p.P31= | Silent (SNP) | VAF 22/208 reads (11%) | catalogued as rs182961814, COSV55631349; called by muse, mutect2, varscan2
- COL6A3 | c.6592-46C>T | Intron (SNP) | VAF 26/56 reads (46%) | catalogued as rs200942887; called by muse, mutect2, varscan2
